Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5400, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5400-01A (Primary Tumor).

PATIENT HISTORY:

No clinical history is given.

PRE-OP DIAGNOSIS: Right renal mass.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Right nephrectomy.

FINAL DIAGNOSIS:**KIDNEY, RIGHT, NEPHRECTOMY –**

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE WITH MASSIVE NECROSIS, CALCIFICATIONS AND FOCAL SARCOMATOID CHANGES WITH RHABDOID MORPHOLOGY (SLIDE J).
- B. FUHRMAN NUCLEAR GRADE IV/ IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 8.0 cm.
- D. THE NEOPLASM FOCALLY EXTENDS INTO THE RENAL SINUS FAT (SLIDE E).
- E. RENAL VEIN TUMOR THROMBUS IS IDENTIFIED.
- F. RENAL VEIN MARGIN IS INVOLVED BY CARCINOMA. ALL OTHER SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- G. THE NON-NEOPLASTIC KIDNEY SHOWS FOCAL GLOBAL GLOMERULOSCLEROSIS, FOCAL TUBULAR ATROPHY AND PROMINENT LYMPHOCYTIC INTERSTITIAL INFILTRATE.
- H. TNM STAGE: pT3b NX MX.
-

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY KIDNEY TUMORS**

SPECIMEN TYPE: Other: NEPHRECTOMY

LATERALITY: Right

TUMOR SITE: Lower pole

FOCALITY: Unifocal

TUMOR SIZE: Greatest dimension: 8.0 cm

Additional dimensions: 7.8 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor extension into perinephric tissues

Tumor extension into major veins

HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma

Sarcomatoid carcinoma arising in renal cell carcinoma

Subtype and % of sarcomatoid element: RHABDOID, 5%

HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G4

PATHOLOGIC STAGING (pTNM): pT3b

pNX

Number of regional lymph nodes examined: 0

pMX

MARGINS: Margin(s) involved by invasive carcinoma

Renal vein margin

ADRENAL GLAND: Not present

VENOUS (LARGE VESSEL) INVASION (V): Present

LYMPHATIC (SMALL VESSEL) INVASION (L): Present

ADDITIONAL PATHOLOGIC FINDINGS: Glomerular disease (type): GLOBAL FOCAL GLOMERULOSCLEROSIS

Interstitial disease (type): LYMPHOCYTIC INFILTRATE

Source: NCI Genomic Data Commons file 4258f589-7fe7-4fc7-aaa6-66ac0594de71 (TCGA-B0-5400.09A0384B-837F-4161-ABEC-7B96AB605186.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).